CPTAC case C3L-02893 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dbdb6b82-5425-41d2-909f-afed671d04df

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 72.1 years (26,331 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1c; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 455 days (1.2 years); Progression or recurrence: yes; Days to last follow up: 455 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 18; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 455 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 455 days (1.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 208 days.

Other clinical attributes
- Weight: 63.5 kg; Height: 152.4 cm; BMI: 27.34; DLCO (% of predicted): 79; FEV1/FVC before bronchodilator (%): 76; FEV1 before bronchodilator (% of reference): 87.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 7; Cigarettes per day: 20; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 1972; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02893-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 180 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02893-22: Section location: Right Upper Lobe; Percent tumor nuclei: 65; Percent necrosis: 3.
- Sample C3L-02893-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 640 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02893-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
